Somatic mutation profile of tumor specimen MP2PRT-PAUYKE-TMP1-A (aliquot MP2PRT-PAUYKE-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUYKE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 4.6 years (1,671 days).
Specimen MP2PRT-PAUYKE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36d65176-5caf-4941-b263-d0c7745ea797.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUYKE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUYKE-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00cea6c6-c688-4954-87e4-6a1fb36dc63e

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 11, Silent 5, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RIT1 | c.268A>G p.M90V | Missense Mutation (SNP) | VAF 59/316 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1557960039, CM167019, COSV64170951; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GRM3 | c.2167C>T p.R723W | Missense Mutation (SNP) | VAF 85/253 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs560446375, COSV64469346; called by muse, mutect2, varscan2
- ITGB5 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.672); catalogued as rs747514529, COSV56146645; called by muse, mutect2, varscan2
- MYO10 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs764784266; called by muse, mutect2
- NETO2 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 84/278 reads (30%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs555638989, COSV57452773, COSV57454155; called by muse, mutect2, varscan2
- SFTPD | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 83/408 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as rs547905862; called by muse, mutect2, varscan2
- UNC5D | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 80/263 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.616); catalogued as rs1192773107; called by muse, mutect2, varscan2
- BNC1 | c.1492C>A p.P498T | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CACNA1I | c.5127C>G p.Y1709* | Nonsense Mutation (SNP) | VAF 102/283 reads (36%) | called by muse, mutect2, varscan2
- CCDC88A | c.2799G>C p.E933D | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- DPP6 | c.1867C>A p.P623T (on ENST00000377770 / NM_001364500.2; = p.P561T on NM_001936.5) | Missense Mutation (SNP) | VAF 118/298 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- OR13C2 | c.943_944del p.F315Lfs*2 | Frame Shift Del (DEL) | VAF 40/124 reads (32%) | called by mutect2, pindel*, varscan2
- PRDM9 | c.373A>T p.S125C | Missense Mutation (SNP) | VAF 71/181 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- CYP1B1 | c.798C>G p.R266= | Silent (SNP) | VAF 16/515 reads (3%) | called by muse, mutect2
- HINFP | c.762C>T p.H254= | Silent (SNP) | VAF 11/220 reads (5%) | catalogued as rs1291936135; called by muse, mutect2
- MIB2 | c.543C>T p.A181= | Silent (SNP) | VAF 192/411 reads (47%) | catalogued as rs757896311; called by muse, mutect2, varscan2
- PCDHGB5 | c.1512C>T p.S504= | Silent (SNP) | VAF 19/348 reads (5%) | called by muse, mutect2
- TAOK2 | c.3663G>T p.R1221= | Silent (SNP) | VAF 136/408 reads (33%) | called by muse, mutect2, varscan2
